Somatic mutation profile of tumor specimen TCGA-V3-A9ZY-01A (aliquot TCGA-V3-A9ZY-01A-11D-A39W-08) from TCGA case TCGA-V3-A9ZY, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.5 years (19,894 days).
Specimen TCGA-V3-A9ZY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b37f34a-5cf4-44b7-b798-4764a596e7f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V3-A9ZY-10A (Blood Derived Normal), aliquot TCGA-V3-A9ZY-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23607712-8b7b-4809-9b41-c0b6a5645322

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRIA1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs751038792; called by muse, mutect2, varscan2
- KIR3DL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs376049512, COSV54390025; called by muse, mutect2, varscan2
- NLRP11 | c.2177T>C p.M726T | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs773018512; called by muse, mutect2, varscan2
- PCDHGA2 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53986833; called by muse, mutect2, varscan2
- EIF1AX | c.208T>A p.W70R | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC4B | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- PDS5B | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRSS16 | c.1157C>G p.T386S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- UNC79 | c.5547_5561del p.Q1849_D1854delinsH (on ENST00000393151 / NM_001346218.2; = p.Q1672_D1677delinsH on NM_020818.5) | In Frame Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- COBL | c.2841A>G p.G947= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- PTPRB | c.474G>A p.S158= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs376545279; called by muse, mutect2, varscan2
- ZNF229 | c.999C>T p.N333= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs754489162, COSV52161507; called by muse, mutect2, varscan2
- MIR518E | n.38T>G | RNA (SNP) | VAF 64/118 reads (54%) | called by muse, mutect2, varscan2
